Gene-level copy-number profile of tumor specimen AP-HML4-4G from APOLLO case AP-HML4, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2.
Specimen AP-HML4-4G: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6b042dd0-ee63-4c77-bc4e-5a2fb2ad623e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-HML4-64 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,395 have no estimate.
https://portal.gdc.cancer.gov/files/91c854a0-90a6-407d-9a96-7b5f46148d38

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,467; copy number 1: 20,417; copy number 2: 22,740; copy number 3: 11,114; copy number 4: 782; copy number 5: 250; copy number 6: 43; copy number 7: 182; copy number 8: 23; copy number 9: 58; copy number 10: 6; copy number 11: 66; copy number 13: 45; copy number 14: 28; copy number 15: 7.

Homozygous deletions (total copy number 0; autosomes only): 2,467 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:18,954,943–18,955,049, 1 gene: RNU6-138P.
- chr3:41,766,615–41,766,919, 1 gene (within-gene range 0–1): RN7SKP58.
- chr3:120,908,072–121,546,641, 8 genes: STXBP5L, AC072026.1, MIR5682, AC078857.1, AC079841.1, AC079841.2, POLQ, RPL7AP11.
- chr6:33,540,694–33,541,000, 1 gene (within-gene range 0–2): RN7SL26P.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr8:36,987,977–43,674,591, 172 genes (broad region; genes not listed).
- chr8:69,667,046–71,228,629, 30 genes (within-gene range 0–1): SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA.
- chr8:84,678,798–86,561,498, 47 genes (within-gene range 0–1): PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1, REXO1L8P, REXO1L3P, REXO1L1P, REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3.
- chr8:86,593,755–86,594,589, 1 gene (within-gene range 0–1): MIOXP1.
- chr9:4,386,410–6,727,438, 70 genes (within-gene range 0–1) (broad region; genes not listed).
- chr9:6,734,598–6,748,981, 2 genes (within-gene range 0–1): PRELID3BP11, SNRPEP2.
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–1): RN7SL5P.
- chr9:40,883,634–68,540,883, 233 genes (broad region; genes not listed).
- chr9:110,873,263–113,429,690, 60 genes: LPAR1, RNU6-432P, Y_RNA, RNY4P18, AL162414.1, MIR7702, OR2K2, ECPAS, RNA5SP294, ZNF483, PTGR1, AL135787.1, LRRC37A5P, DNAJC25, DNAJC25-GNG10, GNG10, SHOC1, AL354877.1, RNU6-1013P, UGCG, MIR4668, RNU6-710P, AL138756.1, SUSD1, RNU6-855P, Y_RNA, AL158824.1, PTBP3, RN7SL57P, RNA5SP295, RN7SL430P, HSPE1P28, AL359073.1, HSDL2, C9orf147, KIAA1958, AL445187.1, INIP, AL390067.1, SNX30, SLC46A2, AL139041.1, ZNF883, MUPP, ZNF883, ZFP37, FAM225B, FAM225A, SLC31A2, FKBP15, SLC31A1, CDC26, PRPF4, RNF183, WDR31, BSPRY, HDHD3, ALAD, POLE3, C9orf43.
- chr9:124,878,275–138,253,217, 449 genes (within-gene range 0–1) (broad region; genes not listed).
- chr10:38,601,418–38,783,108, 8 genes: ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:50,279,828–54,725,816, 16 genes: AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1, OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr11:63,032,503–63,410,294, 10 genes: AP001858.1, TUBAP7, SLC22A24, RPL29P22, SLC22A10, SLC22A25, AP001880.2, CCND2P1, AP001880.1, SLC22A9.
- chr15:19,878,555–23,039,572, 149 genes (broad region; genes not listed).
- chr19:186,373–22,532,485, 1,202 genes (within-gene range 0–1) (broad region; genes not listed).
- chr21:10,649,400–10,649,835, 1 gene: IGHV1OR21-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 708 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:190,878,145–192,957,713, 14 genes, copy number 5 (within-gene range 4–5): AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680, LINC02770, AL359081.1, RGS18, AL390957.1, AL513175.1, AL513175.2, RGS21, AL136987.1, RGS1.
- chr1:196,225,779–197,201,293, 14 genes, copy number 5: KCNT2, MIR4735, CFH, CFHR3, CFHR1, BX248415.1, CFHR4, CFHR2, AL139418.1, CFHR5, F13B, ASPM, SEPTIN14P12, ZBTB41.
- chr1:199,752,491–200,214,322, 10 genes, copy number 5: AL596266.1, AL445687.1, RNU6-778P, AL445687.2, RNU6-716P, RNU6-609P, NR5A2, RNU6-570P, AC096633.1, CCNQP1.
- chr1:202,590,596–204,728,106, 78 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:246,509,038–248,303,424, 90 genes, copy number 5 (broad region; genes not listed).
- chr8:96,645,242–97,358,478, 6 genes, copy number 5: CPQ, AP003117.2, AP003117.1, AP003115.1, TSPYL5, SNORD3H.
- chr8:101,492,439–101,669,726, 1 gene, copy number 5 (within-gene range 4–5): GRHL2.
- chr8:101,562,008–102,418,953, 13 genes, copy number 5: AP001207.1, NCALD, AP000426.1, AP001329.1, PDCL3P2, MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19, UBR5, AP002907.1, AP002981.1.
- chr12:12,310–38,133, 3 genes, copy number 5: DDX11L8, WASH8P, FAM138D.
- chr12:22,409,237–24,562,544, 17 genes, copy number 14 (within-gene range 2–14): AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1, MIR920, SOX5-AS1.
- chr12:26,121,991–26,299,290, 1 gene, copy number 15 (within-gene range 3–15): SSPN.
- chr12:26,139,249–26,335,856, 6 genes, copy number 15 (within-gene range 1–15): AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3.
- chr12:38,082,046–41,932,592, 46 genes, copy number 7–9: CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1.
- chr12:57,128,483–57,213,361, 1 gene, copy number 9 (within-gene range 3–9): LRP1.
- chr12:57,194,504–59,524,184, 74 genes, copy number 9–14 (broad region; genes not listed).
- chr12:67,989,445–68,234,686, 1 gene, copy number 13 (within-gene range 2–13): IFNG-AS1.
- chr12:68,143,318–69,855,363, 51 genes, copy number 7–13 (within-gene range 2–13): AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2.
- chr12:84,154,434–88,602,195, 39 genes, copy number 11–13: AC090679.2, AC090679.1, AC087888.1, AC093027.1, SLC6A15, AC128657.1, TSPAN19, LRRIQ1, ALX1, LINC02820, AC126471.1, AC137768.1, RASSF9, NTS, MGAT4C, AC016993.1, AC139697.1, AC010196.1, AC079597.1, RPL23AP68, AC079598.4, CYCSP30, AC079598.2, MKRN9P, LINC02258, AC079598.1, AC079598.3, RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364, AC091516.1, TMTC3, Y_RNA, KITLG, AC024941.2, RNU1-117P, AC024941.1.
- chr12:89,027,757–89,028,522, 1 gene, copy number 11: AC006199.1.
- chr14:22,132,553–22,516,331, 66 genes, copy number 5 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr17:82,519,713–82,945,914, 17 genes, copy number 5 (within-gene range 3–5): FOXK2, AC124283.4, AC124283.3, AC124283.2, AC124283.1, WDR45B, AC124283.5, RAB40B, MIR4525, AC024361.2, FN3KRP, AC024361.3, FN3K, AC024361.1, TBCD, AC068014.1, ZNF750.
- chr20:59,852,667–64,327,972, 158 genes, copy number 6–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18,790. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
